Gene-level copy-number profile of tumor specimen REBC-ADL8-TTP1-A from REBC case REBC-ADL8, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ADL8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9149fe18-a0ee-4a95-b1b4-87a87def6f00.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADL8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/7a8ecbda-58f9-4727-a39d-1524a94393db

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 167; copy number 2: 58,199; copy number 3: 32; copy number 5: 2; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:197,569–209,892, 1 gene, copy number 7: AC079779.1.
- chr3:196,739,857–196,832,647, 1 gene, copy number 5 (within-gene range 2–5): PAK2.
- chr3:196,784,980–196,785,086, 1 gene, copy number 5: RNU6-42P.

Autosomal genes at a single copy (total copy number 1): 167. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
